Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3H1, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3H1-01A (Primary Tumor).

Diagnosis Discrepancy	Follicular Var.	

Reviewer Initials: *AB* Date Reviewed: *11/21/11* *W*

Sex: F

Received:

Pathologist:

Accession:

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to , the section "SPECIMEN" may have been added. ****

DIAGNOSIS

(A) PARATHYROID:

Parathyroid tissue, no tumor present.

(B) TOTAL THYROIDECTOMY:

PAPILLARY THYROID CARCINOMA, FOLLICULAR VARIANT, RIGHT LOBE.

(SEE COMMENT)

diffuse nodular goiter.

One parathyroid gland, no tumor present.

COMMENT

The tumor is 2 cm in greatest dimension and is encapsulated. No definitive evidence of lymphatic invasion is present.

SPECIMEN

(A) PARATHYROID:

(B) TOTAL THYROIDECTOMY:

1 CD-0-3

SNOMED CODES

T-87000,M-83403

Path: carcinoma, papillary, follicular variant
CBCF: carcinoma, papillary, thyroid 8260/3 8340/3
Site: thyroid, NOS C83.9 W
11/30/11

Source: NCI Genomic Data Commons file ab74d12b-ba76-4e0f-84dd-01b8a1204bbf (TCGA-EL-A3H1.AA255733-E90D-43CF-AFE7-853B2CF70B42.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).